MMRF case MMRF_1335 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e5992503-81fd-4ba2-acbb-33901a9d498a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Dead; Days to death: 1,317 days (3.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 44.9 years (16,396 days); ISS stage: III; Days to last known disease status: 1,317 days (3.6 years); Days to last follow up: 1,317 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 352 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 354 days; Days to treatment end: 354 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 463 days (1.3 years); Days to treatment end: 463 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,317.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 493 mg/dL; Immunoglobulin G 5.57 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 5.55 µg/mL; Hemoglobin 5.15 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.45 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 241 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 3.05 mmol/L; Glucose 5.61 mmol/L.
- Day 81 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 8.44 ×10⁹/L; Platelets 407 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 1.83 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 3.74 mmol/L.
- Day 179 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 7.09 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 330 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 7.87 mmol/L.
- Day 267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 1.57 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 14.5 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 362 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 7.48 mmol/L.
- Day 347 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.8 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 1.52 g/L; Beta 2 Microglobulin 0.75 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 7.96 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.81 mmol/L.
- Day 438 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.5 mg/dL; Hemoglobin 6.57 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 356 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 7.21 mmol/L.
- Day 522 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 3.67 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 0.66 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 634: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 3.55 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 718 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 5.61 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.62 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.56 mmol/L.
- Day 805 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.58 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.1 mmol/L; Glucose 4.35 mmol/L.
- Day 876: Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.4 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 2.01 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.74 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 988: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 75 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 7.04 mmol/L.
- Day 1,065: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 110 mg/dL; Immunoglobulin G 4.29 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 4.35 mmol/L.
- Day 1,166 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 366 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 6.82 mmol/L.
- Day 1,217: Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 329 mg/dL; Hemoglobin 3.84 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.96 ×10⁹/L; Platelets 2 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.78 mmol/L; Albumin 31 g/L; Total Protein 5.2 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day -6: Weight: 91 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1335_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
